Somatic mutation profile of tumor specimen TCGA-CV-5439-01A (aliquot TCGA-CV-5439-01A-01D-1683-08) from TCGA case TCGA-CV-5439, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.1 years (22,686 days).
Specimen TCGA-CV-5439-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fef6246-f01b-4b84-a8ec-ac5e703c460b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5439-11B (Solid Tissue Normal), aliquot TCGA-CV-5439-11B-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0735cfed-2210-4e31-80a1-1f32d6cebf78

The open-access MAF lists 110 somatic variants for this specimen: 81 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 26, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 3, Intron 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5237G>A p.G1746D (on ENST00000272895 / NM_173076.3; = p.G1428D on NM_015657.3) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780541179, COSV99787601; called by muse, mutect2, varscan2
- ABCA9 | c.810G>A p.W270* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100382492; called by muse, mutect2, varscan2
- ADAMTS12 | c.1770G>T p.L590F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100710034; called by muse, mutect2, varscan2
- ADGRB3 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99482987, COSV99483918; called by muse, mutect2, varscan2
- AFF3 | c.2498A>G p.K833R | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs1328154624, COSV100416940; called by muse, mutect2, varscan2
- ALPK3 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV99359939; called by muse, mutect2, varscan2
- APBA1 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 196/495 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99595206; called by muse, mutect2, varscan2
- ARHGAP21 | c.5834C>T p.S1945F | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100255573; called by muse, mutect2
- ARHGAP21 | c.244-2A>T p.X82_splice | Splice Site (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100903463; called by muse, mutect2
- ATP2C2 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1567699346, COSV99297301; called by muse, mutect2, varscan2
- ATP7A | c.4248G>C p.E1416D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV100430067, COSV58445432; called by muse, mutect2
- CCN3 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99422619; called by muse, mutect2, varscan2
- CDH3 | c.1150G>T p.E384* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99867153; called by muse, mutect2, varscan2
- CEP164 | c.3827G>T p.S1276I | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99632288; called by muse, mutect2, varscan2
- CHD7 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs191435594, COSV101417922; called by muse, mutect2, varscan2
- CLTCL1 | c.3494G>A p.R1165H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs372594770; called by muse, mutect2, varscan2
- CPXCR1 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99341880; called by muse, mutect2, varscan2
- CRACR2A | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV99364402; called by muse, mutect2, varscan2
- CYP4F2 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV99171029; called by muse, mutect2, varscan2
- DACT1 | c.1432A>G p.S478G | Missense Mutation (SNP) | VAF 101/151 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100241460; called by muse, mutect2, varscan2
- FABP1 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99860685; called by muse, mutect2, varscan2
- FAM47A | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV100649641; called by muse, mutect2, varscan2
- FAT1 | c.1444del p.V482Sfs*2 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as COSV71672022; called by mutect2, pindel, varscan2
- FEZ1 | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.436); catalogued as COSV99630104; called by muse, mutect2, varscan2
- GDF9 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as COSV51526334; called by muse, mutect2, varscan2
- GRIN2A | c.3917G>T p.R1306M | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV100407384; called by muse, mutect2, varscan2
- GRIN3A | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs747665255, COSV100701306; called by muse, mutect2, varscan2
- HABP4 | c.607A>G p.R203G | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs953815071, COSV100928238; called by muse, mutect2, varscan2
- HAVCR1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 84/425 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as rs114193906, COSV59400630; called by muse, mutect2, varscan2
- HSPB3 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as COSV100115842; called by muse, mutect2
- HYAL1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs781788934, COSV56496934; called by muse, mutect2
- ITGA2B | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99288420; called by muse, mutect2, varscan2
- KBTBD3 | c.1424G>T p.C475F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101595651; called by muse, mutect2, varscan2
- KCNJ5 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1390322659, COSV57964605; called by muse, mutect2, varscan2
- KIF2B | c.630A>T p.Q210H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV99274418; called by muse, mutect2, varscan2
- KRT77 | c.1427+2T>C p.X476_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100526876; called by muse, mutect2, varscan2
- LILRB1 | c.1099C>A p.Q367K (on ENST00000427581; = p.Q331K on NM_006669.6) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.748); catalogued as COSV100206737; called by muse, mutect2, varscan2
- LPA | c.5060A>T p.Y1687F | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV100305756, COSV60314110; called by muse, mutect2, varscan2
- LRP6 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99741999; called by muse, mutect2, varscan2
- LRRC4C | c.1736C>A p.T579K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.021); catalogued as COSV99536471; called by muse, mutect2, varscan2
- MACF1 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100481665; called by muse, mutect2, varscan2
- MAN1B1 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100814382; called by muse, varscan2
- MAP3K19 | c.448A>T p.R150W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV100207823; called by muse, mutect2, varscan2
- MGST1 | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99163146; called by muse, mutect2
- NAV1 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99817986; called by muse, mutect2, varscan2
- NCALD | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636388; called by muse, mutect2, varscan2
- NLRC5 | c.5032A>T p.T1678S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs762970987, COSV99346135; called by muse, mutect2, varscan2
- NOTCH1 | c.283G>T p.G95W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99484030; called by muse, mutect2
- NPAP1 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100274534, COSV61510472; called by muse, mutect2, varscan2
- NUP153 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100019571; called by muse, mutect2, varscan2
- PLCD4 | c.1091T>C p.V364A | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV101346825; called by muse, mutect2, varscan2
- PLEKHJ1 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99677513; called by muse, mutect2, varscan2
- POLR1A | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99806927; called by muse, mutect2, varscan2
- RIMS1 | c.2588A>T p.H863L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99322748; called by muse, mutect2, varscan2
- RYR3 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as rs764639699, COSV66811601; called by muse, mutect2, varscan2
- SAMD7 | c.242A>T p.K81M | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100156675; called by muse, mutect2
- SEC16B | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100381089; called by muse, mutect2, varscan2
- SLC17A8 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV100035006, COSV60126339; called by muse, mutect2, varscan2
- SLC45A1 | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99238084; called by muse, mutect2, varscan2
- SYNE1 | c.20633G>T p.R6878L (on ENST00000367255 / NM_182961.4; = p.R6807L on NM_033071.3) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775765441, COSV54967006, COSV99549252; called by muse, mutect2, varscan2
- TERF1 | c.888-2A>G p.X296_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99400759; called by muse, mutect2
- TIMELESS | c.77A>T p.H26L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as COSV99973424, COSV99973764; called by muse, mutect2, varscan2
- TNIK | c.2504A>G p.E835G | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1210637985, COSV99454069; called by muse, mutect2, varscan2
- TRANK1 | c.3715T>A p.S1239T | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV100080837; called by muse, mutect2, varscan2
- TRPV4 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as CM103097, COSV99924228; called by muse, mutect2, varscan2
- USP54 | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as COSV100160802; called by muse, mutect2, varscan2
- ZBTB9 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV101221714; called by muse, mutect2, varscan2
- ZFP37 | c.1658C>A p.A553D | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100953111; called by muse, mutect2, varscan2
- ZNF536 | c.916G>C p.D306H | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100834499; called by muse, mutect2, varscan2
- ZNF561 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV57177664; called by muse, mutect2
- ZNF695 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.307); catalogued as COSV100377175; called by muse, mutect2, varscan2
- ZNF804B | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100301127; called by muse, mutect2, varscan2
- GMIP | c.2460del p.T821Hfs*50 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- IGHJ4 | c.3C>A p.Y1* | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2
- IGKV1D-8 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MAGEC1 | c.1104del p.Q370Sfs*17 | Frame Shift Del (DEL) | VAF 88/153 reads (58%) | called by mutect2, pindel, varscan2
- MARF1 | c.512del p.G171Afs*11 | Frame Shift Del (DEL) | VAF 48/164 reads (29%) | called by mutect2, pindel, varscan2
- SLC18A3 | c.891del p.L298Sfs*19 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- STK33 | c.846del p.T283Hfs*27 | Frame Shift Del (DEL) | VAF 43/147 reads (29%) | called by mutect2, pindel, varscan2
- TP53 | c.949dup p.Q317Pfs*20 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- TRGC2 | c.187A>T p.M63L | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMPH | c.1590C>A p.L530= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs201328417, COSV100340349, COSV57736176; called by muse, mutect2, varscan2
- APOB | c.5604C>A p.L1868= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV99262740; called by muse, mutect2, varscan2
- ARHGDIB | c.153G>T p.T51= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV57456430, COSV99967216; called by muse, mutect2, varscan2
- ASCL1 | c.654T>C p.S218= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99901848; called by muse, mutect2, varscan2
- ATRX | c.5166T>C p.H1722= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as COSV64884065; called by muse, mutect2, varscan2
- DCAF15 | c.837G>A p.A279= | Silent (SNP) | VAF 155/200 reads (78%) | catalogued as rs199921180, COSV54327696; called by muse, mutect2, varscan2
- FFAR3 | c.168C>T p.N56= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs578021833, COSV100588086; called by muse, mutect2, varscan2
- FRMPD2 | c.2352T>C p.R784= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100563383; called by muse, mutect2, varscan2
- KCNH3 | c.1734G>A p.L578= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1347719272, COSV99234554; called by muse, mutect2, varscan2
- MYH3 | c.312C>T p.Y104= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV99877500; called by muse, mutect2, varscan2
- NIBAN1 | c.2277C>T p.H759= | Silent (SNP) | VAF 78/244 reads (32%) | catalogued as COSV100836123; called by muse, mutect2, varscan2
- OR8J1 | c.447C>T p.Y149= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100274794; called by muse, mutect2, varscan2
- PC | c.2670C>A p.V890= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100546912; called by muse, mutect2, varscan2
- PDE8B | c.645G>T p.S215= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99365867; called by muse, mutect2, varscan2
- PKDREJ | c.3780C>T p.T1260= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV99478247; called by muse, mutect2, varscan2
- POGK | c.633T>C p.Y211= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100902396; called by muse, mutect2, varscan2
- RANBP9 | c.1182C>T p.D394= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99163481; called by muse, mutect2, varscan2
- SERPINE1 | c.987C>T p.F329= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99776493; called by muse, mutect2, varscan2
- TMEM145 | c.756C>T p.L252= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV56624081; called by muse, mutect2
- TMEM59L | c.555G>T p.V185= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV99449842; called by muse, mutect2, varscan2
- TRAPPC12 | c.1710G>T p.S570= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100159917; called by muse, mutect2, varscan2
- TRGC2 | c.186C>A p.T62= | Silent (SNP) | VAF 57/249 reads (23%) | called by muse, mutect2, varscan2
- USH2A | c.13338C>T p.N4446= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as rs369514651; called by muse, mutect2, varscan2
- USP28 | c.423C>T p.R141= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99134359; called by muse, mutect2, varscan2
- Z83844.2 | c.1698G>T p.T566= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs368413888, COSV99312748; called by muse, mutect2, varscan2
- ZNF561 | c.546A>T p.P182= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1434983516, COSV100254218; called by muse, mutect2
- FOLH1B | n.1429G>C | RNA (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- GABRG2 | c.1248+300C>A | Intron (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- SVIL | c.827+5508G>A | Intron (SNP) | VAF 11/40 reads (28%) | catalogued as rs376672879; called by muse, mutect2
